Somatic mutation profile of tumor specimen TCGA-KL-8346-01A (aliquot TCGA-KL-8346-01A-11D-2310-10) from TCGA case TCGA-KL-8346, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 62.0 years (22,651 days).
Specimen TCGA-KL-8346-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef1bd289-4c68-4648-9a34-54cc58395119.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8346-11A (Solid Tissue Normal), aliquot TCGA-KL-8346-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1856d67b-2385-47b4-94f3-d1bd7fc136e3

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10B | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 68/93 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762149091, COSV59164051; called by muse, mutect2, varscan2
- CHRD | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs375530942, COSV99200330; called by muse, mutect2, varscan2
- COL16A1 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 68/72 reads (94%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1269145053; called by muse, mutect2, varscan2
- CPSF7 | c.641G>A p.R214H (on ENST00000394888 / NM_001136040.4; = p.R257H on NM_024811.4) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs758991309; called by muse, mutect2, varscan2
- GDPD5 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs911567347; called by muse, mutect2, varscan2
- KLHL33 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs766135630; called by muse, mutect2, varscan2
- OR10K1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 67/90 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs746569386, COSV56870742, COSV99193195; called by muse, mutect2, varscan2
- PDS5A | c.3711G>C p.K1237N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); catalogued as COSV100337147; called by muse, mutect2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs759883814, COSV56092392; called by pindel, varscan2
- TAL1 | c.767C>A p.T256N | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV53749089; called by muse, mutect2, varscan2
- TOP2B | c.4342_4346del p.F1448Ifs*11 (on ENST00000264331 / NM_001330700.2; = p.F1443Ifs*11 on NM_001068.3) | Frame Shift Del (DEL) | VAF 72/144 reads (50%) | catalogued as rs1354762612; called by mutect2, pindel, varscan2
- MAPKBP1 | c.2699A>C p.H900P (on ENST00000456763 / NM_001128608.2; = p.H894P on NM_014994.3) | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PPM1K | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, varscan2
- PTK2 | c.2502A>G p.K834= | Splice Region (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- ATN1 | c.1065A>C p.S355= | Silent (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- FAM117B | c.1041A>G p.E347= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- VAPA | c.636T>A p.P212= (on ENST00000400000 / NM_194434.3; = p.P257= on NM_003574.6) | Silent (SNP) | VAF 81/201 reads (40%) | called by muse, mutect2, varscan2
